Somatic mutation profile of tumor specimen 0DTD38 from CCDI case PBCJJY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 20.6 years (7,539 days).
Specimen 0DTD38: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b8a01b3-1fad-4089-a02f-ecf7ad7b5f8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTD36 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80a59f8c-e0f0-4ab0-aac8-9f3b72043049

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Intron 3, 5'UTR 2, Nonsense Mutation 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM3 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 288/682 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs550153768; called by muse, mutect2, varscan2
- BMP3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 296/708 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51088415; called by muse, mutect2, varscan2
- CDK8 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 310/485 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67422799; called by muse, mutect2, varscan2
- CNTNAP3B | c.1993C>A p.Q665K | Missense Mutation (SNP) | VAF 40/655 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1218665459; called by muse, mutect2
- CRB2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 123/227 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1474833179, COSV63503082; called by muse, mutect2, varscan2
- IGF2 | c.223G>A p.A75T (on ENST00000434045 / NM_001127598.3; = p.A19T on NM_000612.6) | Missense Mutation (SNP) | VAF 144/306 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.239); catalogued as rs975030738, COSV56099060; called by muse, mutect2, varscan2
- KRTAP4-9 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs1231970295; called by muse, varscan2
- RAD54L2 | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 275/581 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.466); catalogued as rs747266400, COSV56578426; called by muse, mutect2, varscan2
- TMC1 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 264/583 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52775683; called by muse, mutect2, varscan2
- TRMT44 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 238/515 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs989786284, COSV67663721; called by muse, mutect2, varscan2
- DMXL1 | c.5244dup p.V1749Sfs*10 | Frame Shift Ins (INS) | VAF 342/762 reads (45%) | called by mutect2, varscan2
- KMT2C | c.3472C>T p.Q1158* | Nonsense Mutation (SNP) | VAF 405/895 reads (45%) | called by muse, mutect2, varscan2
- LAMC1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2
- STAG1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 276/648 reads (43%) | called by muse, mutect2, varscan2
- UBTF | c.135G>C p.K45N | Missense Mutation (SNP) | VAF 276/1115 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF570 | c.1552A>G p.R518G | Missense Mutation (SNP) | VAF 195/484 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- CLVS2 | c.60C>T p.L20= | Silent (SNP) | VAF 392/900 reads (44%) | catalogued as COSV99253194; called by muse, mutect2, varscan2
- HIF1A | c.2067C>T p.N689= | Silent (SNP) | VAF 281/664 reads (42%) | catalogued as rs776789375, COSV60191841; called by muse, mutect2, varscan2
- MED15 | c.1668C>T p.N556= (on ENST00000263205 / NM_001003891.3; = p.N516= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 165/340 reads (49%) | catalogued as rs770051230; called by muse, mutect2, varscan2
- SEC24D | c.954T>C p.C318= | Silent (SNP) | VAF 426/895 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.324+30G>A | Intron (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- B4GALT3 | c.-7C>T | 5'UTR (SNP) | VAF 237/516 reads (46%) | called by muse, mutect2, varscan2
- IRAK1 | c.541-11T>A | Intron (SNP) | VAF 75/313 reads (24%) | called by muse, mutect2, varscan2
- NFYC | c.388-52G>A | Intron (SNP) | VAF 98/168 reads (58%) | catalogued as rs1158990023; called by muse, mutect2, varscan2
- PLA2G12A | c.-5C>G | 5'UTR (SNP) | VAF 77/165 reads (47%) | called by muse, mutect2, varscan2
- SLC7A13 | c.*66G>C | 3'UTR (SNP) | VAF 72/392 reads (18%) | called by muse, mutect2, varscan2
